Somatic mutation profile of tumor specimen 0DOV9J from CCDI case PBCCRU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 3.1 years (1,130 days).
Specimen 0DOV9J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59cef682-b493-46aa-ad6a-a1ab4f4f5a9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a4639b0-e911-4af7-9369-c7beab3fb893

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAML1 | c.5666T>C p.F1889S (on ENST00000321322; = p.F1829S on NM_020693.4) | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209108336; called by muse, mutect2
- ESAM | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as rs745435981, COSV54036153; called by muse, mutect2, varscan2
- PIMREG | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV51470247; called by muse, mutect2
- PTPN14 | c.2558A>T p.Q853L | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.628); called by muse, mutect2
